Somatic mutation profile of tumor specimen TARGET-10-PARPGW-09A (aliquot TARGET-10-PARPGW-09A-01D) from TARGET case TARGET-10-PARPGW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,620 days).
Specimen TARGET-10-PARPGW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c673a26-e61a-4a41-b304-4e631ea7cf0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPGW-10A (Blood Derived Normal), aliquot TARGET-10-PARPGW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ec50f89-9aed-4993-a441-472ffd39cc3d

The open-access MAF lists 76 somatic variants for this specimen: 49 protein-altering or splice-affecting, 9 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Intron 9, Silent 9, 3'UTR 6, Nonsense Mutation 4, Splice Region 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.238); catalogued as rs1373884931; called by muse, mutect2, varscan2
- ARL5A | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1215342829; called by muse, mutect2
- ATF7IP | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs149615634; called by muse, mutect2, varscan2
- ATRNL1 | c.4052C>T p.S1351L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV58117165; called by muse, mutect2, varscan2
- COBLL1 | c.779C>T p.S260F (on ENST00000392717; = p.S222F on NM_014900.5) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376899183; called by muse, varscan2
- EPHA6 | c.2526G>C p.M842I (on ENST00000389672 / NM_001080448.3; = p.M234I on NM_173655.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV67582026; called by muse, mutect2, varscan2
- FANCM | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV57497834; called by muse, mutect2, varscan2
- FILIP1L | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100496664; called by muse, mutect2
- KPNA7 | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as rs1475158567; called by muse, mutect2, varscan2
- MIA2 | c.2351C>G p.S784* | Nonsense Mutation (SNP) | VAF 52/95 reads (55%) | catalogued as COSV54492144, COSV99698061; called by muse, mutect2, varscan2
- MUC6 | c.5123C>G p.S1708* | Nonsense Mutation (SNP) | VAF 16/310 reads (5%) | catalogued as rs1490197766; called by muse, mutect2
- MYH8 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1363461295; called by muse, mutect2, varscan2
- RAI14 | c.2439G>C p.E813D | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV54291374; called by muse, mutect2, varscan2
- SEPTIN14 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as COSV66427520; called by muse, mutect2, varscan2
- TTN | c.38746G>C p.D12916H (on ENST00000591111; = p.D5492H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | PolyPhen benign (0.421); catalogued as COSV60181732; called by muse, mutect2, varscan2
- ALKBH2 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2
- ANAPC15 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.981); called by muse, mutect2
- ATP2B1 | c.3274G>C p.E1092Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CADPS | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCNT2 | c.1192G>C p.D398H | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- CDC40 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2
- CDCA2 | c.2737C>G p.P913A | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- CENPE | c.3450G>A p.M1150I | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CENPI | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COL6A5 | c.5023G>A p.D1675N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRNN | c.1265C>G p.P422R | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- ESYT2 | c.701C>A p.T234N (on ENST00000613624; = p.T158N on NM_020728.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FSIP2 | c.4940C>G p.S1647* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- GAB2 | c.117G>A p.M39I (on ENST00000361507 / NM_080491.3; = p.M1? on NM_012296.3) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- GCNA | c.1428G>C p.K476N | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GOLGB1 | c.1138C>G p.H380D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HYAL4 | c.911C>G p.T304R | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IRF3 | c.982+7G>A | Splice Region (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- LTN1 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- MYO1B | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOBOX | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2, varscan2
- PLK3 | c.1165-4C>T | Splice Region (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- PPA1 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); called by muse, mutect2
- PTPRZ1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- RIPK2 | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SENP1 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SLC4A9 | c.2077G>C p.E693Q (on ENST00000507527 / NM_001258428.2; = p.E669Q on NM_031467.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC7A5 | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SP100 | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- STAU2 | c.415C>G p.H139D (on ENST00000524300 / NM_001164380.2; = p.H107D on NM_014393.2) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SYNPO2 | c.2671G>C p.D891H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- TUBA3C | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- UFM1 | c.95T>A p.V32D | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYM6 | c.3168G>C p.E1056D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- ARHGEF26 | c.687G>A p.E229= | Silent (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- EMC8 | c.558C>T p.F186= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1445147929, COSV53667600; called by muse, mutect2, varscan2
- HARS2 | c.1149C>T p.L383= | Silent (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- IRF3 | c.81G>C p.V27= | Silent (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- MYLK3 | c.2169C>T p.F723= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as COSV67367348; called by muse, mutect2, varscan2
- NEB | c.18474C>G p.V6158= | Silent (SNP) | VAF 32/86 reads (37%) | called by muse, mutect2, varscan2
- SERPINA12 | c.969C>A p.L323= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs746060479, COSV57943136; called by muse, mutect2, varscan2
- TENM2 | c.79C>T p.L27= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- YIF1A | c.867C>T p.F289= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs763366695; called by muse, mutect2, varscan2
- ABCA7 | c.4881-52C>G | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- AFF3 | chr2:100106156 C>A | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- ATXN2 | c.2998+53G>A | Intron (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- CEP170 | c.1567-3960C>G | Intron (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- COL4A5 | c.-26G>A | 5'UTR (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.*20G>A | 3'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101131107; called by muse, mutect2, varscan2
- DCTN2 | c.105+3071G>C | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- DOCK5 | c.3816+75G>A | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- FAM177B | c.242-410G>T | Intron (SNP) | VAF 45/90 reads (50%) | catalogued as rs1431636834; called by muse, mutect2, varscan2
- H2BC7 | c.*33C>G | 3'UTR (SNP) | VAF 31/79 reads (39%) | catalogued as COSV100587197; called by muse, mutect2, varscan2
- LAPTM4B | c.*109G>A | 3'UTR (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- MYO9A | c.6837+1403C>G | Intron (SNP) | VAF 16/136 reads (12%) | called by muse, mutect2, varscan2
- PABPC5 | c.-27G>A | 5'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- PAX4 | c.144+115C>T | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- PNISR | c.*416C>G | 3'UTR (SNP) | VAF 18/32 reads (56%) | catalogued as rs1356569789; called by muse, mutect2, varscan2
- TNRC6A | c.4123-32C>G | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as rs748984812; called by muse, mutect2, varscan2
- ZHX3 | c.*212C>G | 3'UTR (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- ZNF613 | c.*36C>T | 3'UTR (SNP) | VAF 19/49 reads (39%) | catalogued as rs559800623; called by muse, mutect2, varscan2
